Somatic mutation profile of tumor specimen HTMCP-03-06-02367-01A (aliquot HTMCP-03-06-02367-01A-01D-10409) from CGCI case HTMCP-03-06-02367, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86b412ba-1ea1-4af9-b57e-0d1aa38be93a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02367-10A (Blood Derived Normal), aliquot HTMCP-03-06-02367-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d54c4b3-69da-463d-b341-860d2b06a5b1

The open-access MAF lists 42 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs746570916, COSV52033924; called by muse, mutect2, varscan2
- ENPP2 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 25/176 reads (14%) | catalogued as rs776028490, COSV50038815; called by muse, mutect2, varscan2
- ERICH3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1319714520, COSV100443473; called by muse, mutect2, varscan2
- EZH2 | c.1823G>A p.R608Q (on ENST00000460911 / NM_001203247.2; = p.R613Q on NM_004456.5) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs561605379, COSV100236491; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1562C>G p.P521R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100438146; called by muse, mutect2, varscan2
- GOLGA4 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs768320250; called by muse, mutect2, varscan2
- HSPG2 | c.8152G>A p.G2718S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778350928; called by muse, varscan2
- LAMA1 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs762641681, COSV101056591, COSV67544778; called by muse, mutect2, varscan2
- MGAM | c.4519G>A p.V1507I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as rs527929510, COSV72075420, COSV72075783; called by muse, mutect2, varscan2
- NDNF | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs199541505; called by muse, mutect2, varscan2
- RADIL | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753252335, COSV68202264; called by muse, mutect2, varscan2
- SDK1 | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as rs200464210; called by muse, mutect2, varscan2
- SDK2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746724792, COSV66193172, COSV66197263; called by mutect2, varscan2
- SLC32A1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.547); catalogued as COSV54148490; called by muse, mutect2, varscan2
- SLITRK1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65674844; called by muse, mutect2, varscan2
- TNXB | c.8137G>A p.V2713M (on ENST00000647633; = p.V2466M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs369070722; called by muse, mutect2, varscan2
- UBR2 | c.3299C>T p.P1100L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs747465280; called by muse, mutect2, varscan2
- VCAN | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1214212199, COSV54098125, COSV54111597; called by muse, mutect2, varscan2
- CHD2 | c.4456C>T p.L1486F | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLEC14A | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 58/65 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- CTTN | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- DOCK11 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FAM50A | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HSPG2 | c.11081C>T p.P3694L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IQCN | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC12 | c.2629G>T p.A877S (on ENST00000379442; = p.A734S on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/575 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PIBF1 | c.911_912del p.K304Rfs*16 | Frame Shift Del (DEL) | VAF 11/109 reads (10%) | called by mutect2, pindel
- PTPRM | c.2892_2908del p.P965Yfs*11 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- TTN | c.89225T>C p.V29742A (on ENST00000591111; = p.V22318A on NM_003319.4) | Missense Mutation (SNP) | VAF 56/208 reads (27%) | PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TUBB2A | c.107dup p.Y36* | Nonsense Mutation (INS) | VAF 15/136 reads (11%) | called by mutect2, pindel, varscan2
- ZFR | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 117/275 reads (43%) | called by muse, mutect2, varscan2
- AKNAD1 | c.210C>T p.T70= | Silent (SNP) | VAF 99/333 reads (30%) | called by muse, mutect2, varscan2
- CSDE1 | c.1113T>C p.R371= (on ENST00000358528 / NM_001007553.3; = p.R340= on NM_007158.6) | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- KIF16B | c.3003G>A p.Q1001= | Silent (SNP) | VAF 14/268 reads (5%) | catalogued as COSV61705151; called by muse, mutect2
- MAP4K1 | c.1224C>T p.D408= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs201024197; called by muse, varscan2
- MUC5B | c.10494C>T p.T3498= | Silent (SNP) | VAF 52/254 reads (20%) | called by muse, mutect2, varscan2
- MYRIP | c.1356C>T p.C452= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1461100933; called by muse, mutect2, varscan2
- PKD1L1 | c.4104T>C p.I1368= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1530G>A p.A510= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs188565967; called by mutect2, varscan2
- EYS | c.1766+2606A>T | Intron (SNP) | VAF 19/82 reads (23%) | catalogued as rs918786874; called by muse, mutect2, varscan2
- TPO | c.2748+17C>T | Intron (SNP) | VAF 9/71 reads (13%) | catalogued as rs778044030; called by muse, mutect2, varscan2
- ZNF653 | c.*103G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
